Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8QC, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8QC-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Biopsy of the cervix.

- Moderately differentiated and infiltrative squamous cell carcinoma.

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site Cervix NOS
C53.9

pre 3/8/14

qIPAA Discrepancy		☒
Metastatic Malignancy History		☒

Source: NCI Genomic Data Commons file d1443121-438a-4914-ab98-e4710590b8d7 (TCGA-VS-A8QC.2A1AB5DB-9963-41C6-B28F-1A26D149930C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).